Gene-level copy-number profile of tumor specimen TCGA-N5-A4RT-01A from TCGA case TCGA-N5-A4RT, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 69.5 years (25,386 days).
Specimen TCGA-N5-A4RT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.a4caf9d4-6daf-4e04-aa62-e3243fedd3b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3ac51f8-7d8e-4163-9665-0b9bd393672f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 429; copy number 2: 21,599; copy number 3: 17,417; copy number 4: 15,464; copy number 5: 2,549; copy number 6: 1,328; copy number 7: 342; copy number 8: 162; copy number 9: 96; copy number 11: 162; copy number 12: 49; copy number 14: 12; copy number 19: 147; copy number 27: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RT-01A-11D-A28Q-01): tumor purity 0.91, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,337 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,600,621–173,064,015, 30 genes, copy number 6 (within-gene range 4–6): MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1.
- chr1:235,328,570–235,448,952, 1 gene, copy number 5 (within-gene range 4–5): AL357556.3.
- chr1:235,367,360–248,919,946, 315 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:79,025,686–83,595,243, 40 genes, copy number 5–6: REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10.
- chr2:182,833,275–182,866,637, 1 gene, copy number 5 (within-gene range 3–5): FRZB.
- chr3:37,969,404–38,137,242, 7 genes, copy number 7 (within-gene range 3–7): MIR26A1, VILL, PLCD1, Y_RNA, DLEC1, PPP2R2DP1, ACAA1.
- chr3:48,517,684–48,740,353, 15 genes, copy number 6: PFKFB4, MIR6823, UCN2, COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1, NCKIPSD, IP6K2.
- chr3:129,647,792–198,222,513, 1,192 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr4:49,096–1,982,207, 73 genes, copy number 5–8 (broad region; genes not listed).
- chr4:1,986,384–1,986,477, 1 gene, copy number 8: MIR943.
- chr5:58,198–3,601,403, 92 genes, copy number 5 (broad region; genes not listed).
- chr5:23,688,927–45,895,970, 328 genes, copy number 5–9 (broad region; genes not listed).
- chr5:176,726,942–177,474,401, 25 genes, copy number 6 (within-gene range 2–6): AC113391.2, LINC01574, UNC5A, HK3, UIMC1, ZNF346, ZNF346-IT1, FGFR4, NSD1, AC146507.3, AC146507.2, PRMT1P1, RAB24, MXD3, PRELID1, LMAN2, AC146507.1, RGS14, SLC34A1, PFN3, F12, GRK6, PRR7-AS1, PRR7, DBN1.
- chr6:168,716,606–170,738,536, 52 genes, copy number 5: AL136099.1, AL513210.2, AL513210.1, AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr8:46,579,213–48,194,627, 42 genes, copy number 5 (within-gene range 4–5): ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1.
- chr8:61,714,788–62,249,879, 9 genes, copy number 5: MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1.
- chr8:102,125,432–104,256,094, 52 genes, copy number 5 (within-gene range 4–5): MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:114,282,067–114,791,929, 3 genes, copy number 5: AC064802.1, AC025881.1, CARS1P2.
- chr8:119,419,910–128,187,101, 150 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:33,921,693–34,048,949, 1 gene, copy number 5 (within-gene range 3–5): UBAP2.
- chr9:34,049,966–34,343,711, 14 genes, copy number 5: RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1, KIF24, RNU2-50P, SERPINH1P1, NUDT2.
- chr11:167,784–491,399, 30 genes, copy number 5: BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9, RN7SL838P, PTDSS2, AC138230.1.
- chr11:47,164,299–47,905,607, 39 genes, copy number 5: ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA, NUP160, AC021443.1, RNA5SP340, Y_RNA, YPEL5P2, AC023232.1.
- chr12:19,724,435–20,688,583, 10 genes, copy number 5: RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1.
- chr12:24,212,421–24,949,101, 10 genes, copy number 5: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2.
- chr12:52,715,567–53,054,450, 20 genes, copy number 6 (within-gene range 4–6): KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1.
- chr17:38,996,323–41,930,542, 179 genes, copy number 9–12 (within-gene range 2–12) (broad region; genes not listed).
- chr17:50,934,989–51,297,936, 11 genes, copy number 5: AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18.
- chr17:78,248,193–78,577,396, 14 genes, copy number 5 (within-gene range 3–5): AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P.
- chr19:29,083,094–40,808,418, 466 genes, copy number 8–27 (within-gene range 3–27) (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 5 (broad region; genes not listed).
- chr20:14,003,508–14,636,524, 8 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1.
- chr20:44,475,874–45,254,564, 29 genes, copy number 5: TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, AL049767.1, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI.
- chr20:49,038,357–49,484,297, 16 genes, copy number 5: SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.
- chr21:10,328,411–46,665,124, 745 genes, copy number 5–6 (broad region; genes not listed).
- chr22:22,988,263–23,402,726, 16 genes, copy number 5: AC245054.2, AC245054.1, RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2.
- chr22:37,339,583–37,427,445, 1 gene, copy number 7 (within-gene range 4–7): ELFN2.
- chr22:37,367,960–37,807,436, 19 genes, copy number 7: ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0.

Autosomal genes at a single copy (total copy number 1): 429. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
